Surgical pathology report (de-identified scan), TCGA case TCGA-H2-A422, project TCGA-THCA (Thyroid Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-H2-A422-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

A. Thyroid, right lobe, excision:
Papillary thyroid carcinoma, 3 CM (pT2)
Resection margins negative for malignancy
Background chronic inflammation
Benign adherent skeletal muscle

B. Thyroid, left lobe, excision:
Benign thyroid parenchyma
3 benign lymph nodes (0/3)
Single benign normocellular intrathyroidal parathyroid gland

Microscopic Description:

Microscopic examination performed.
Histologic type: Papillary carcinoma, classical type
Primary tumor (pT): 3 cm in greatest dimension, limited to thyroid (pT2)
Margins of resection: Negative for tumor
Vascular invasion: Identified
Regional lymph nodes (pN): In 3 lymph nodes are identified attached to the left lobe and they're all negative for metastatic tumor (pN0)
Distant metastasis (pM): Not evaluated (pMx)
Other findings: A single benign normocellular parathyroid gland in slide B3 (left inferior) is identified. No tall cell are columnar cell features are identified in the papillary carcinoma.

Specimen

A. Thyroid, right lobe, excision
B. Left thyroid lobe

Clinical Information

Mass right lobe of thyroid with suspicious cells

Intraoperative Consultation

A. Right thyroid lobe, excision: Papillary thyroid carcinoma.

Gross Description

A. Received fresh for frozen section and tissue procurement labeled "A. Right thyroid lobe" is a 15.3 g, 6 x 3 x 2.8 cm lobe of thyroid. The central aspect of the thyroid lobe is distorted by a large palpable nodule. The resection margins are inked and the specimen is serially sectioned to reveal a cystic mass with friable papillary appearing tumor measuring 3 cm in greatest dimension. A representative touch prep is made and a representative frozen section is performed. Representative tissue was submitted for tissue procurement. The remaining tissue is entirely submitted in a sequential fashion blocks 2 through 8.

1CD-0-3
Carcinoma, papillary, thyroid
826013

Site: thyroid, NOS
C73.9

7-23-12 RD

[page 2 of 2]
B. Received in formalin labeled "left thyroid lobe" is a 5 g pink-tan irregular rubbery thyroid lobe. The possible isthmus margin is inked orange the remainder of the specimen is inked blue. The specimen is pink tan and rubbery. The specimen is sectioned from superior to inferior to show a pink red spongy cut surface with no other discrete gross lesions identified. The specimen is entirely submitted from superior to inferior in 3 cassettes.

Source: NCI Genomic Data Commons file 10e779a8-e17e-4bdf-90be-e257e3e6bd04 (TCGA-H2-A422.84172B64-F859-431E-A98A-23B7CDCB276E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).